Somatic mutation profile of tumor specimen TCGA-ER-A19S-06A (aliquot TCGA-ER-A19S-06A-11D-A196-08) from TCGA case TCGA-ER-A19S, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 81.1 years (29,639 days).
Specimen TCGA-ER-A19S-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae5049bd-dbca-45cf-9f61-cd36d42c9502.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19S-10A (Blood Derived Normal), aliquot TCGA-ER-A19S-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6348e5d-194f-4eab-a262-d5b52be6ed5a

The open-access MAF lists 225 somatic variants for this specimen: 149 protein-altering or splice-affecting, 72 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, Silent 72, Nonsense Mutation 10, Intron 2, Splice Site 2, 3'UTR 1, Frame Shift Ins 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- SF3B1 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775623976, COSV59205859, COSV59212489, COSV59228873; ClinVar: likely pathogenic; called by mutect2, varscan2
- ABCA3 | c.3805G>A p.E1269K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.317); catalogued as rs776731355, COSV57061176; called by muse, mutect2, varscan2
- ADAM10 | c.1079C>T p.T360I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53055451; called by muse, mutect2, varscan2
- ADAM20 | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV56456883; called by muse, mutect2
- ADAMTS19 | c.3293G>A p.R1098Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.103); catalogued as rs267600341, COSV50759770; called by muse, mutect2, varscan2
- ADPRH | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV63694385; called by muse, mutect2, varscan2
- AGBL1 | c.2140A>G p.T714A | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV66857359, COSV66876354, COSV99069532; called by muse, mutect2
- AGGF1 | c.356A>C p.N119T | Missense Mutation (SNP) | VAF 48/310 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV57231505; called by muse, mutect2, varscan2
- AGT | c.626T>C p.V209A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs751978314, COSV64185642; called by muse, mutect2
- ALPI | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs779742623, COSV55016469; called by muse, mutect2, varscan2
- AOX1 | c.2012T>G p.V671G | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV65984642; called by muse, mutect2
- AP3M2 | c.25A>T p.N9Y | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51531039; called by muse, mutect2, varscan2
- APOL4 | c.398T>G p.I133S (on ENST00000352371 / NM_145660.2; = p.I130S on NM_030643.4) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV60655534; called by muse, mutect2, varscan2
- ARFGEF3 | c.4226C>T p.P1409L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV52455481; called by muse, mutect2, varscan2
- ATP7A | c.1866T>G p.I622M | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV58455601; called by muse, mutect2
- BRINP2 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1418455034, COSV64177622; called by muse, mutect2, varscan2
- BUB1B | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs918041637, COSV55017564; called by muse, mutect2, varscan2
- C1QTNF8 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV60519362; called by muse, mutect2, varscan2
- CAMTA1 | c.2425G>A p.G809R | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.674); catalogued as rs748817784, COSV57895427; called by muse, mutect2, varscan2
- CAMTA1 | c.2426G>A p.G809E | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); catalogued as COSV100352413, COSV100352692; called by muse, mutect2, varscan2
- CCDC110 | c.399T>G p.F133L | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.033); catalogued as COSV56873798; called by muse, mutect2
- CDC42BPB | c.4925C>T p.P1642L | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1287079702, COSV63477220; called by muse, mutect2
- CDC42BPB | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as COSV63476784; called by muse, mutect2
- CDH13 | c.1012G>T p.G338* | Nonsense Mutation (SNP) | VAF 29/221 reads (13%) | catalogued as COSV51826670, COSV51875911; called by muse, mutect2, varscan2
- CDSN | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); catalogued as COSV52537855; called by muse, mutect2, varscan2
- CEL | c.386G>A p.G129E (on ENST00000673714; = p.G126E on NM_001807.6) | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60830036; called by muse, mutect2, varscan2
- CEP170B | c.3871A>G p.S1291G (on ENST00000453495; = p.S1220G on NM_015005.3) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV52045747; called by muse, mutect2, varscan2
- CHUK | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.074); catalogued as COSV64918867; called by muse, mutect2
- COL11A1 | c.1901G>A p.G634E | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV62180545; called by muse, mutect2
- COL27A1 | c.2162G>A p.G721E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61931445; called by muse, mutect2, varscan2
- COL6A3 | c.3722C>T p.S1241F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55087972; called by muse, mutect2, varscan2
- CSRNP3 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as rs867148664, COSV58783305; called by muse, mutect2, varscan2
- CYP4F22 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs189645644, COSV54111496; called by muse, mutect2, varscan2
- DAB2 | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as COSV57919627; called by muse, mutect2, varscan2
- DISP3 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs754090573, COSV53822055; called by muse, mutect2, varscan2
- DNAH6 | c.1627C>T p.H543Y | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV52886965; called by muse, mutect2, varscan2
- DNAH9 | c.13151A>G p.N4384S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.06); catalogued as COSV52380905; called by muse, mutect2, varscan2
- DNM2 | c.1759G>A p.A587T (on ENST00000355667 / NM_001005360.3; = p.A583T on NM_004945.3) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV58973325; called by muse, mutect2, varscan2
- DNMT3L | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV54266476; called by muse, mutect2
- DOCK11 | c.3764C>T p.T1255I | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52249020; called by muse, mutect2
- DOCK3 | c.3563C>T p.S1188F | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs868683773, COSV56501731; called by muse, mutect2, varscan2
- DPY19L3 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60480807; called by muse, mutect2, varscan2
- DSG3 | c.2977G>A p.D993N | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV57130239; called by muse, mutect2, varscan2
- EDEM2 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV65713838; called by muse, mutect2, varscan2
- EFCC1 | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV71402239; called by muse, mutect2, varscan2
- ELAVL2 | c.827G>A p.W276* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV56372596; called by muse, mutect2, varscan2
- EP400 | c.9154C>T p.Q3052* | Nonsense Mutation (SNP) | VAF 7/78 reads (9%) | catalogued as COSV57788707; called by muse, mutect2
- ESYT1 | c.3053A>G p.K1018R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV57277118; called by muse, mutect2, varscan2
- ETV3L | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs199857262, COSV71901232; called by muse, mutect2, varscan2
- EXOC3 | c.95A>T p.Y32F | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV59269108; called by muse, mutect2
- F5 | c.292A>G p.I98V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV63129335; called by muse, mutect2, varscan2
- FAM47A | c.2115G>A p.W705* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | catalogued as COSV60500333; called by muse, mutect2, varscan2
- FER1L6 | c.2509G>A p.G837S | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.13); catalogued as COSV67553267; called by muse, mutect2, varscan2
- FOXM1 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV61207342; called by muse, mutect2, varscan2
- FTSJ3 | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as rs148527553; called by muse, mutect2, varscan2
- GABRA1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1457242041, COSV50098975; called by muse, mutect2, varscan2
- GDF5 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV100976751, COSV65503916; called by muse, mutect2
- GFRA3 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 9/74 reads (12%) | catalogued as COSV51232411; called by muse, mutect2, varscan2
- GLRA4 | c.1121G>C p.R374P | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV60327540, COSV60328491; called by muse, mutect2, varscan2
- GTF3C2 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53129104; called by muse, mutect2, varscan2
- H4C2 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV55137492, COSV55141384; called by muse, mutect2, varscan2
- HMGCLL1 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51441241; called by muse, mutect2, varscan2
- HTRA1 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100934811, COSV64564118; called by muse, mutect2, varscan2
- HUWE1 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53366787; called by muse, mutect2, varscan2
- IGLV6-57 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV66504395; called by muse, mutect2, varscan2
- IGSF1 | c.491T>G p.F164C | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV63840921; called by muse, mutect2
- IL1RAP | c.47T>G p.L16R | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV50773388; called by muse, mutect2, varscan2
- KCNH5 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as rs371757416; called by muse, mutect2, varscan2
- KCTD10 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV57327164; called by muse, mutect2, varscan2
- KMT2A | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV63293510; called by muse, mutect2, varscan2
- KRTAP10-10 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV59951846, COSV59982734; called by muse, mutect2, varscan2
- LAMA2 | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs781728421, COSV70345083; ClinVar: uncertain significance; called by mutect2, varscan2
- LGR6 | c.1685G>A p.W562* (on ENST00000367278 / NM_001017403.1; = p.W510* on NM_021636.3) | Nonsense Mutation (SNP) | VAF 13/94 reads (14%) | catalogued as COSV55167783; called by muse, mutect2, varscan2
- MAGEA6 | c.506T>G p.V169G | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as rs1556826487, COSV61449583; called by muse, mutect2
- MAGEC1 | c.3082G>A p.V1028M | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53582740; called by muse, mutect2
- MCHR2 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as rs200390537, COSV56009277; called by muse, mutect2, varscan2
- MORC4 | c.1591C>T p.H531Y | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV55241625, COSV55244980; called by muse, mutect2
- MRGPRX1 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 15/253 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV57110125; called by muse, mutect2
- MRPL43 | c.368A>G p.N123S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.028); catalogued as COSV52972736; called by muse, mutect2
- MUC16 | c.10607C>T p.P3536L | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); catalogued as rs1379151005, COSV67459101; called by muse, mutect2
- MUC17 | c.4289C>T p.S1430F | Missense Mutation (SNP) | VAF 35/316 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV60306648; called by muse, mutect2, varscan2
- MYCBP2 | c.8519C>T p.P2840L (on ENST00000357337; = p.P2878L on NM_015057.5) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV62042369; called by muse, mutect2, varscan2
- MYH2 | c.2964G>A p.M988I | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV55439879; called by muse, mutect2, varscan2
- MYH7 | c.3853+1G>T p.X1285_splice | Splice Site (SNP) | VAF 15/104 reads (14%) | catalogued as COSV62524899; called by muse, varscan2
- NCKAP1L | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53213288; called by muse, mutect2, varscan2
- NLRP13 | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as rs200519393, COSV61624417; called by muse, mutect2, varscan2
- NOTCH4 | c.917G>A p.W306* | Nonsense Mutation (SNP) | VAF 75/256 reads (29%) | catalogued as COSV66684506; called by muse, mutect2, varscan2
- NOX1 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as rs145941822, COSV54194183; called by muse, mutect2
- NPPA | c.249G>C p.W83C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100412235; called by muse, mutect2, varscan2
- NPPA | c.248G>A p.W83* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100412236; called by muse, mutect2, varscan2
- NRK | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54608833; called by muse, mutect2, varscan2
- NWD1 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs139108504, COSV60353457; called by muse, mutect2, varscan2
- OR11H12 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs369314954; called by muse, mutect2, varscan2
- OR11L1 | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV63313995; called by muse, mutect2, varscan2
- OR13A1 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs780110354, COSV65573666; called by mutect2, varscan2
- OR6V1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs867782093, COSV69237344; called by muse, mutect2, varscan2
- PAK5 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62039716; called by muse, mutect2, varscan2
- PAK5 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62039723; called by muse, mutect2, varscan2
- PCDHA10 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV56553088; called by muse, mutect2, varscan2
- PCDHA8 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.144); catalogued as COSV65340362; called by muse, mutect2, varscan2
- PCDHGB1 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.049); catalogued as COSV54050014; called by muse, mutect2, varscan2
- PCLO | c.1685G>A p.G562E | Missense Mutation (SNP) | VAF 82/457 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100434624, COSV61634120; called by muse, mutect2, varscan2
- PDE7A | c.1390A>G p.T464A (on ENST00000401827 / NM_001242318.3; = p.T438A on NM_002603.4) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV65154713; called by muse, mutect2, varscan2
- PEX7 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs1393448051, COSV59247821; called by muse, mutect2
- PIP4K2A | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.106); catalogued as COSV100114733; called by muse, mutect2, varscan2
- PPEF1 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as rs1569257625, COSV62997055; called by muse, mutect2, varscan2
- PRAMEF2 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.201); catalogued as COSV53576192, COSV53580052; called by muse, mutect2, varscan2
- PRDX6 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745706076, COSV61166445; called by muse, mutect2, varscan2
- PRX | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs371562775; called by muse, mutect2
- RAI2 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV100518126, COSV58966580; called by muse, mutect2
- RHOU | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs964164425; called by muse, mutect2
- RIMS1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1044390019, COSV53488608; called by muse, mutect2, varscan2
- SAMD9L | c.3350C>T p.S1117F | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59079287; called by muse, mutect2, varscan2
- SASH3 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63556837; called by muse, mutect2, varscan2
- SCN11A | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV56579748; called by muse, mutect2, varscan2
- SEC31B | c.2918C>T p.P973L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV64846004; called by muse, mutect2, varscan2
- SEMA5B | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778251817, COSV52095129, COSV99533431; called by mutect2, varscan2
- SERPINE1 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as rs370298461, COSV56171879; called by mutect2, varscan2
- SF3B1 | c.3820A>T p.I1274F | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV59229520; called by muse, mutect2
- SHQ1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.178); catalogued as COSV100345292; called by muse, mutect2, varscan2
- SLC12A8 | c.1451G>A p.R484K | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as rs768087718, COSV58864968, COSV58868199; called by muse, mutect2, varscan2
- SLC7A2 | c.719G>A p.G240E (on ENST00000494857 / NM_001370338.1; = p.G280E on NM_003046.6) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV50279095; called by muse, mutect2, varscan2
- SLC7A7 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.97); PolyPhen benign (0.021); catalogued as rs1288195057, COSV53538740; called by muse, mutect2
- SMC5 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.255); catalogued as rs776725660, COSV63195963; called by muse, mutect2, varscan2
- SPTA1 | c.3706G>A p.G1236R | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.58); catalogued as rs1246616441, COSV63756962; called by muse, mutect2, varscan2
- SRSF3 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59672249; called by muse, mutect2
- STAG3 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 43/366 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV57932756, COSV57934185; called by muse, mutect2, varscan2
- TBX22 | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1057515990, COSV64788182; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THBS4 | c.294C>T p.A98= | Splice Region (SNP) | VAF 60/296 reads (20%) | catalogued as COSV63471252; called by muse, mutect2, varscan2
- THEMIS | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.209); catalogued as rs1049532553, COSV64069628, COSV64075353; called by muse, mutect2, varscan2
- TRH | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.422); catalogued as rs1350242063, COSV57015480; called by muse, mutect2, varscan2
- TRIM42 | c.1544T>C p.M515T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV53887571; called by muse, mutect2, varscan2
- TRIML1 | c.1396A>T p.S466C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.338); catalogued as COSV60197267; called by muse, mutect2, varscan2
- TRPC7 | c.1782G>A p.M594I | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.688); catalogued as COSV61465169; called by muse, mutect2, varscan2
- TRPS1 | c.3086A>T p.H1029L (on ENST00000220888 / NM_001330599.2; = p.H1042L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55265779; called by muse, mutect2
- TSPYL2 | c.1238+2T>G p.X413_splice | Splice Site (SNP) | VAF 7/44 reads (16%) | catalogued as COSV60238597, COSV60238724; called by muse, mutect2, varscan2
- UBE3C | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765647551, COSV61955962; called by muse, mutect2, varscan2
- USH2A | c.13816G>A p.E4606K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56450109; called by muse, mutect2
- WDR36 | c.106A>G p.K36E | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV72411062, COSV72411539; called by muse, mutect2
- XPO1 | c.2632A>G p.I878V | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV68948163; called by muse, mutect2
- ZNF230 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV71273796; called by muse, mutect2, varscan2
- ZNF318 | c.4886A>C p.Q1629P | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as COSV58938513; called by muse, mutect2, varscan2
- ZNF326 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs761061308, COSV61036885; called by muse, mutect2, varscan2
- ZNF536 | c.1699G>A p.V567M | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV62821277; called by muse, mutect2, varscan2
- ZNF563 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV53372579; called by muse, mutect2, varscan2
- ZNF770 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.169); catalogued as COSV62545262; called by muse, mutect2, varscan2
- MUC2 | c.1401C>A p.C467* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- TNPO1 | c.1114dup p.I372Nfs*2 | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | called by mutect2, pindel
- ADGRG4 | c.6093T>C p.T2031= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV54969092; called by muse, mutect2, varscan2
- APOB | c.9789C>T p.F3263= | Silent (SNP) | VAF 72/340 reads (21%) | catalogued as rs564227456, COSV51956312; called by muse, mutect2, varscan2
- ATP2B3 | c.1896G>A p.R632= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV54864136; called by muse, mutect2, varscan2
- ATXN7L3 | c.222G>A p.Q74= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as rs1396199618, COSV66989795; called by muse, mutect2, varscan2
- B3GNT3 | c.435C>T p.F145= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100592820, COSV59439370; called by muse, mutect2, varscan2
- CCDC88C | c.1881G>A p.G627= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as rs1216780371; called by muse, mutect2
- CD163 | c.3165G>A p.G1055= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV63138502; called by muse, mutect2, varscan2
- CES2 | c.741C>T p.F247= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs778134567, COSV57696444; called by muse, mutect2, varscan2
- CFAP54 | c.7827C>T p.I2609= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV61575990; called by muse, mutect2, varscan2
- CSRNP3 | c.606C>T p.L202= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV100086497; called by muse, mutect2, varscan2
- CUX2 | c.1689G>A p.K563= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV55650305; called by mutect2, varscan2
- DEPTOR | c.1140C>T p.V380= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV53822932; called by muse, mutect2, varscan2
- DMBT1 | c.7131C>T p.V2377= (on ENST00000338354 / NM_001377530.1; = p.V1620= on NM_004406.3) | Silent (SNP) | VAF 20/165 reads (12%) | catalogued as rs1212721538, COSV57551115, COSV57555576; called by muse, mutect2
- DNAH10 | c.10626C>T p.F3542= (on ENST00000409039; = p.F3481= on NM_207437.3) | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV69004052; called by muse, mutect2
- DNAH3 | c.10650G>A p.Q3550= | Silent (SNP) | VAF 13/145 reads (9%) | catalogued as COSV54557552; called by muse, mutect2
- DNAH5 | c.9957C>T p.I3319= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as rs766420895, COSV54203577; called by muse, mutect2, varscan2
- DNAJB5 | c.138G>A p.K46= | Silent (SNP) | VAF 17/172 reads (10%) | catalogued as COSV56627726; called by muse, mutect2, varscan2
- DPEP2 | c.1161T>G p.G387= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as COSV52056326; called by muse, mutect2, varscan2
- EGFR | c.540C>T p.F180= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs974428039, COSV51855418; called by muse, mutect2, varscan2
- ENC1 | c.645T>C p.I215= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV56631931; called by muse, mutect2
- EP400 | c.8793G>A p.L2931= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV57788697; called by muse, mutect2, varscan2
- ETV7 | c.673C>T p.L225= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV60317393; called by muse, mutect2
- GGTLC1 | c.294C>T p.F98= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV53847135; called by muse, mutect2, varscan2
- GLYCTK | c.474C>T p.I158= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV59794918; called by muse, mutect2, varscan2
- HIPK2 | c.414C>T p.I138= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs745936379, COSV61228627; called by muse, mutect2, varscan2
- HS3ST5 | c.807G>A p.V269= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV57153459; called by muse, mutect2, varscan2
- HUWE1 | c.8082G>A p.R2694= | Silent (SNP) | VAF 8/101 reads (8%) | catalogued as COSV53344656; called by muse, mutect2
- IGHV3-7 | c.117C>T p.L39= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as rs375467224; called by muse, mutect2
- IGSF1 | c.1134C>T p.F378= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV63840916; called by muse, mutect2, varscan2
- ITK | c.795G>A p.R265= | Silent (SNP) | VAF 61/456 reads (13%) | catalogued as COSV68435522; called by muse, mutect2, varscan2
- JADE3 | c.552C>T p.N184= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV54471287; called by muse, mutect2, varscan2
- JAM2 | c.519C>T p.I173= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57257910; called by muse, mutect2, varscan2
- KIRREL2 | c.516C>T p.F172= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV52880894; called by muse, mutect2, varscan2
- KRTAP10-9 | c.807C>T p.S269= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV59982727; called by muse, mutect2, varscan2
- LPO | c.807G>A p.G269= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs777426367, COSV51861423, COSV51863270; called by muse, mutect2, varscan2
- LRP5 | c.4428C>T p.N1476= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV53724782; called by muse, mutect2, varscan2
- LRRTM4 | c.1605C>T p.I535= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV69151719; called by muse, mutect2
- MAGEB18 | c.807C>T p.F269= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV57464689; called by muse, mutect2, varscan2
- MYO7A | c.1314C>T p.I438= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs781868818, COSV68687606; called by muse, mutect2, varscan2
- NOD2 | c.3040C>T p.L1014= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV56055384; called by muse, mutect2
- NRXN1 | c.2022G>A p.K674= | Silent (SNP) | VAF 82/343 reads (24%) | catalogued as rs764163609, COSV58434493, COSV58500103; called by muse, mutect2, varscan2
- OR10H3 | c.318C>T p.F106= | Silent (SNP) | VAF 38/252 reads (15%) | catalogued as COSV59945062; called by muse, mutect2, varscan2
- OR13C5 | c.363C>T p.D121= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV66165443; called by muse, mutect2, varscan2
- OR2M3 | c.600C>T p.F200= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as COSV71759124; called by muse, mutect2, varscan2
- OR51I1 | c.897G>A p.K299= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV66509452; called by muse, mutect2, varscan2
- PADI2 | c.1896C>T p.I632= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs759910803, COSV64953391; called by muse, mutect2, varscan2
- PCDHA9 | c.981C>T p.F327= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs781919355, COSV100970185; called by muse, mutect2, varscan2
- PCDHGB4 | c.2103C>T p.F701= | Silent (SNP) | VAF 9/184 reads (5%) | catalogued as COSV53897151, COSV53956246; called by muse, mutect2
- PGPEP1L | c.222G>A p.R74= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV66710157; called by muse, mutect2, varscan2
- PIP4K2A | c.921C>T p.T307= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as rs1324307391, COSV100114734; called by muse, mutect2, varscan2
- PKDREJ | c.1368C>T p.A456= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs1569006227, COSV53553880; called by muse, mutect2
- PKDREJ | c.942G>A p.G314= | Silent (SNP) | VAF 10/225 reads (4%) | catalogued as COSV53553894; called by muse, mutect2
- PLCXD2 | c.252C>T p.I84= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV67342533; called by muse, mutect2, varscan2
- PRKAR1B | c.1026G>A p.R342= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1342558487, COSV64320300; called by muse, mutect2
- ROS1 | c.6879C>T p.G2293= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs764341045, COSV63862562; called by muse, mutect2, varscan2
- RREB1 | c.1812C>T p.A604= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV58567048; called by muse, mutect2, varscan2
- RYK | c.1575T>A p.A525= (on ENST00000620660 / NM_001005861.2; = p.A522= on NM_002958.4) | Silent (SNP) | VAF 29/199 reads (15%) | catalogued as COSV56064885; called by muse, mutect2, varscan2
- SCN11A | c.768G>A p.V256= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV56572930; called by muse, mutect2, varscan2
- SCN3A | c.768C>T p.F256= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as COSV51806203, COSV51827244; called by muse, mutect2
- SIN3B | c.1410C>T p.S470= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV56137048; called by muse, mutect2, varscan2
- SLC2A9 | c.661C>T p.L221= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV53330233; called by muse, mutect2
- SLC45A1 | c.1536C>T p.L512= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs770426185, COSV57096177, COSV57096819; called by muse, mutect2, varscan2
- SPEF2 | c.1690T>C p.L564= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs755660044, COSV61554377; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2733G>A p.R911= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV59126302; called by muse, mutect2, varscan2
- TLR4 | c.1347C>T p.L449= (on ENST00000355622 / NM_138554.5; = p.L409= on NM_003266.4) | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs1213497608, COSV62923997; called by muse, mutect2, varscan2
- TMPRSS15 | c.573T>C p.C191= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs754490153, COSV53050851; called by muse, mutect2, varscan2
- TRBV27 | c.279C>T p.F93= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- TTBK1 | c.1995C>T p.S665= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as rs373133592, COSV52488204; called by muse, mutect2, varscan2
- TTF2 | c.2919C>T p.S973= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV65633998; called by muse, mutect2, varscan2
- USPL1 | c.2287T>C p.L763= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV55002792; called by muse, mutect2, varscan2
- ZFP41 | c.558C>T p.L186= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV58088641; called by muse, mutect2, varscan2
- ZNF160 | c.1419C>T p.V473= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV62001269; called by muse, mutect2, varscan2
- CLCN5 | c.17-33869C>T | Intron (SNP) | VAF 7/109 reads (6%) | catalogued as COSV65802239; called by muse, mutect2
- GLYCTK | c.*2G>A | 3'UTR (SNP) | VAF 13/30 reads (43%) | catalogued as COSV99980986; called by muse, mutect2, varscan2
- PIK3CD | c.-138+2014G>T | Intron (SNP) | VAF 15/148 reads (10%) | catalogued as COSV66098915; called by muse, mutect2
- SNORD115-2 | n.55C>T | RNA (SNP) | VAF 44/173 reads (25%) | called by muse, mutect2, varscan2
